Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A6FE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A6FE-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: M

Location:

Reported:

Ordering MD:

Facility:

Copy To:

Specimen(s) Received

1. Lymph-Node: ST9 Inf Pulm Ligament
2. Lymph node: Subcarinal ST7
3. Esophagus: Final esophageal margin
4. Esophagus: Thoracic esophagus & proximal stomach

Diagnosis

1. ST9 inferior pulmonary ligament lymph node: one reactive lymph node, negative for malignancy (0/1).
2. Subcarinal ST7 lymph node: one lymph node positive for metastatic carcinoma (1/1).
3. Final esophageal margin: esophageal wall negative for malignancy.
4. Thoracic esophagus & proximal stomach resection specimen: poorly differentiated squamous cell carcinoma with sarcomatoid and rhabdoid features, distal esophagus, invading into the periesophageal fat, 7 of 33 lymph nodes positive for metastatic carcinoma (7/33), (pT3N1c), proximal and distal resection margins clear, radial margin positive for carcinoma. See synoptic report, microscopic description and comment.

Comment

The synoptic report includes all the lymph nodes present for this patient.
In specimen #4, the pTN stage includes all the lymph nodes present for this patient.

ICD-O-3

Synoptic Data

Specimen Type:

Tumor Site:

Tumor Size:

Histologic Type:

Histologic Grade:

Pathologic Staging (pTNM):

Esophagogastrectomy

distal esophagus

Greatest dimension: 10.6 cm

Additional dimensions: 9.0 x 5.5 cm

Squamous cell carcinoma

G3: Poorly differentiated

pT3: Tumor invades adventitia

pN1c: More than 7 nodes involved

Number of lymph nodes examined: 35

Number of lymph nodes involved: 8

Carcinoma, squamous cell NOS
8670/3

Site: Esophagus, distal third
C15.5

JA 6/10/13

[page 2 of 3]
Surgical Pathology Consultation Report

Margins: Proximal margin-Uninvolved by invasive carcinoma
Distal margin-Uninvolved by invasive carcinoma
Circumferential (Adventitial) margin-Involved by invasive carcinoma
Margin: radial

Venous (Large Vessel) Invasion (V): Absent
Lymphatic (Small Vessel) Invasion (L): Absent
Additional Pathologic Findings: None identified

Electronically verified by:

Gross Description

1. The specimen is labeled with the patient's name and as "station 9".
One piece of fibroadipose tissue measuring 0.6 x 0.6 x 0.2 cm.
1A submitted in toto

2. The specimen is labeled with the patient's identification and as "subcarinal ST7".
Number of tissue pieces: 1
Lymph nodes: Multiple coalesced lymph nodes measuring 4.0 x 3.0 x 2.6 cm in maximum dimension grossly thought to be involved by tumor.
2A representative section

3. The specimen is labeled with the patient's identification and as "Final esophageal margin". It consists of a segment of luminal tissue measuring 1.2 cm in length with a diameter of 2.0 cm. It is stapled at one end.
3A full-thickness section adjacent to stapled margin

4. The specimen is labeled with the patient's identification and as "thoracic esophagus and proximal stomach".

RESECTION SPECIMEN: e.g. Subtotal gastro-esophagectomy

FIXATION: Received fresh, placed in formalin

DIMENSIONS:

Length along lesser curvature: 2.0 cm
Length along greater curvature: 6.0 cm
Circumference of distal gastric margin: 11.0 cm
Circumference of proximal gastric margin: Not applicable
Length of tubular esophagus: 16.5 cm
Width of tubular esophagus: Proximal 7.5 cm - 4.5 cm. Distal 11.0 cm - 9.5 cm

TUMOR:

LOCATION:

-Esophagus only:

CONFIGURATION: Exophytic, necrotic, almost circumferential (2.5 cm of spared mucosa)

- DIMENSIONS: Diameters: 10.6 x 9.0 cm
Depth: 5.5 cm

- DESCRIPTIVE CHARACTERISTICS: Fleishy, yellow-tan with congested areas.

- PERFORATION: No

[page 3 of 3]
Surgical Pathology Consultation Report

- DISTANCE FROM MARGINS:

- PROXIMAL 7.5 cm
- DISTAL 2.2 cm
- RADIAL 0.1 cm

ESTIMATED DEPTH OF INVASION: Serosa

LESIONS IN NONCANCEROUS STOMACH: None

LYMPH NODES: Multiple lymph nodes measuring up to 4.5 cm in greatest dimension.

TUMOR BANKING: 3 pieces of tumor, 2 pieces of esophageal mucosa, 1 piece of gastric mucosa

Photographs are taken of the specimen.

Representative sections:

- 4A proximal margin, en face
- 4B esophagus, proximal to tumor
- 4C proximal edge of tumor with adjacent mucosa
- 4D-4I tumor, proximal to distal
- 4J-4K distal edge of tumor with adjacent mucosa including GE junction
- 4L gastric mucosa
- 4M-4N distal margin, en face
- 4O multiple lymph nodes, paraesophageal
- 4P 1 lymph node, bisected, paraesophageal
- 4Q 1 representative slice, 1 lymph node, paraesophageal
- 4R-4W multiple lymph nodes, per block, gastric
- 4X 1 lymph node, bisected, gastric
- 4Y-4AA 1 representative slice of 1 lymph node, per block, gastric

Microscopic Description

Neoplastic cells show patchy positivity for pan-CK and CK7 and diffuse positivity for p63, negative for LMWK, HMWK, CK20, S100, desmin and caldesmon.

Source: NCI Genomic Data Commons file 4536b989-8d4c-42a8-aa48-9dccc8c05947 (TCGA-JY-A6FE.B3CA2230-E92C-4FFF-809B-968130ADE935.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).